Somatic mutation profile of tumor specimen TCGA-DM-A28H-01A (aliquot TCGA-DM-A28H-01A-11D-A16V-10) from TCGA case TCGA-DM-A28H, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 50.2 years (18,325 days).
Specimen TCGA-DM-A28H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77ff04a7-97fc-4d8d-a83a-6d8e5ccb1780.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A28H-10A (Blood Derived Normal), aliquot TCGA-DM-A28H-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23ce4da5-fbaa-4aae-9ec2-c01686741f07

The open-access MAF lists 133 somatic variants for this specimen: 106 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 26, Frame Shift Ins 6, Nonsense Mutation 6, Splice Region 4, Frame Shift Del 4, In Frame Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 32/69 reads (46%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 46/112 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61684436, COSV61688043; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 20/25 reads (80%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB11 | c.2068A>T p.S690C | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV55600519; called by muse, mutect2, varscan2
- ACRV1 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV59755388; called by muse, mutect2, varscan2
- ADAM29 | c.1180A>C p.I394L | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV63667910; called by muse, mutect2, varscan2
- ADAMTS16 | c.2839G>A p.A947T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV56996336, COSV57006264; called by muse, mutect2, varscan2
- ADGRV1 | c.13510A>G p.R4504G | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV101316447, COSV67978378; called by muse, mutect2, varscan2
- AFF2 | c.563A>G p.Q188R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.357); catalogued as COSV100650881; called by muse, mutect2
- AFF3 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.699); catalogued as rs369487993, COSV57872410; called by muse, mutect2, varscan2
- ALMS1 | c.8524C>T p.H2842Y | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV100043391; called by muse, mutect2
- AP002512.3 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs199694619, COSV54405850; called by muse, mutect2, varscan2
- APMAP | c.849_850del p.R283Sfs*12 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs770805855; called by pindel, varscan2
- ARFGEF1 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 123/185 reads (66%) | catalogued as COSV99144099; called by muse, mutect2, varscan2
- ASTN2 | c.2628C>A p.G876= (on ENST00000313400 / NM_001365069.1; = p.G825= on NM_014010.5) | Splice Region (SNP) | VAF 11/26 reads (42%) | catalogued as COSV57816075; called by muse, mutect2, varscan2
- BRWD1 | c.4664C>T p.S1555F | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as COSV60896221; called by muse, mutect2, varscan2
- CASS4 | c.1208C>G p.S403C | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV64388365; called by muse, varscan2
- CCDC127 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1332870264, COSV57258000; called by muse, mutect2, varscan2
- CDH19 | c.1872G>T p.Q624H | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV100051018; called by muse, mutect2, varscan2
- CHD9 | c.1486A>T p.T496S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV101272169; called by muse, varscan2
- CLCA2 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65288653; called by muse, mutect2, varscan2
- CNBD2 | c.1702C>T p.R568W (on ENST00000373973 / NM_001365709.1; = p.R564W on NM_080834.4) | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373220798; called by muse, mutect2, varscan2
- CNTN5 | c.467C>G p.T156S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs1463459682, COSV99680182; called by muse, mutect2, varscan2
- COL11A1 | c.4974A>G p.V1658= | Splice Region (SNP) | VAF 21/67 reads (31%) | catalogued as COSV62196505; called by muse, mutect2, varscan2
- CST7 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771107712, COSV54176899; called by muse, mutect2, varscan2
- CYP3A7 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146249663, COSV60483285; called by muse, mutect2, varscan2
- DENND4B | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs751314491, COSV63410129; called by muse, mutect2, varscan2
- DGKG | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs200662645; called by muse, mutect2, varscan2
- DPRX | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs1429358956, COSV64949959; called by muse, mutect2, varscan2
- DYNC2H1 | c.3644G>A p.R1215H | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs1157870566, COSV62106169; called by muse, mutect2, varscan2
- EPS8L3 | c.788_789insA p.S264Qfs*23 | Frame Shift Ins (INS) | VAF 134/405 reads (33%) | catalogued as COSV62610495; called by mutect2, pindel, varscan2
- ERCC6 | c.2030C>T p.P677L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749619397, COSV63394155; called by muse, mutect2, varscan2
- FLRT2 | c.135C>A p.N45K | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.193); catalogued as COSV58149730; called by muse, mutect2, varscan2
- GOLPH3 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV54062519; called by muse, mutect2, varscan2
- GPR34 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59375079; called by muse, mutect2, varscan2
- GRM1 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 62/79 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV51111904; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2537A>G p.D846G (on ENST00000265755 / NM_016328.3; = p.D831G on NM_005685.4) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as rs782812850, COSV56091661; called by muse, mutect2, varscan2
- HERC4 | c.2563G>T p.D855Y (on ENST00000395198 / NM_022079.3; = p.D847Y on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99517362; called by muse, mutect2, varscan2
- IGF2R | c.3484G>A p.A1162T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs372971885; called by muse, mutect2, varscan2
- IL17RC | c.1282G>A p.E428K (on ENST00000295981 / NM_153461.4; = p.E342K on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs368679093, COSV55973656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JPH3 | c.2179A>C p.I727L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV52473759; called by muse, mutect2, varscan2
- KCTD8 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs200347865, COSV63586189; called by muse, mutect2, varscan2
- KRT84 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs1022162839, COSV57771852; called by muse, mutect2, varscan2
- LRP1B | c.3886C>G p.H1296D | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV101259636; called by muse, mutect2, varscan2
- LRP2 | c.6164A>T p.N2055I | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as COSV99789849; called by muse, mutect2, varscan2
- LRRC32 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1305581122, COSV52635359; called by muse, mutect2, varscan2
- METTL16 | c.1262A>T p.E421V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as COSV99563735; called by mutect2, varscan2
- MTERF2 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as COSV53528554; called by muse, mutect2, varscan2
- MTMR4 | c.3392A>T p.K1131I | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV60203552; called by muse, mutect2, varscan2
- MYCBP2 | c.11757C>A p.F3919L (on ENST00000357337; = p.F3957L on NM_015057.5) | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV62038157; called by muse, mutect2, varscan2
- MYO5A | c.2546G>A p.R849Q | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs754654495, COSV62564531; called by muse, mutect2, varscan2
- MYPN | c.3935G>A p.R1312Q | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs761812034, COSV62733162; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NDUFAF1 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770333609, COSV52976396; called by muse, mutect2, varscan2
- NEK4 | c.1937G>T p.G646V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV99238041; called by muse, mutect2, varscan2
- NFASC | c.757G>A p.A253T (on ENST00000339876 / NM_001378329.1; = p.A264T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs535350909, COSV58373975, COSV99046033; called by muse, mutect2, varscan2
- NPAP1 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV100275971, COSV104413159; called by muse, mutect2, varscan2
- NUDT3 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV74119452; called by muse, mutect2, varscan2
- OR13F1 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs75217962, COSV58252604; called by muse, mutect2, varscan2
- OR6C68 | c.774C>G p.I258M | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.334); catalogued as rs746977620, COSV65563896; called by muse, mutect2, varscan2
- OR8G2P | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs768703651; called by muse, mutect2, varscan2
- PAPPA | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1025262255, COSV60285567, COSV60291318; called by muse, mutect2, varscan2
- PAX8 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.898); catalogued as rs1349026936, COSV54511939; called by muse, mutect2, varscan2
- PCDHB12 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs782691165, COSV53396750; called by muse, mutect2, varscan2
- PCDHB5 | c.1310C>T p.T437M | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); catalogued as rs781801829, COSV50669283, COSV99169356; called by muse, mutect2, varscan2
- PCDHGA7 | c.1654G>A p.V552M | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); catalogued as rs756336021, COSV53918962, COSV53956234; called by muse, mutect2, varscan2
- PHKB | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs544216921, COSV54533456; called by muse, mutect2, varscan2
- PLEKHG4B | c.902C>T p.P301L (on ENST00000283426; = p.P657L on NM_052909.5) | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.092); catalogued as COSV52054736; called by muse, mutect2, varscan2
- POLR1A | c.2637A>G p.A879= | Splice Region (SNP) | VAF 11/41 reads (27%) | catalogued as COSV99808252; called by muse, mutect2
- PRKD1 | c.2506C>A p.H836N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100121332; called by muse, mutect2, varscan2
- PRMT2 | c.27A>C p.R9S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as COSV52457841; called by muse, mutect2, varscan2
- RELN | c.7702A>C p.N2568H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV100634569; called by muse, mutect2, varscan2
- RFC5 | c.663G>A p.Q221= | Splice Region (SNP) | VAF 12/45 reads (27%) | catalogued as COSV57478746; called by muse, mutect2, varscan2
- RGMA | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1413387031, COSV61236722; called by muse, mutect2, varscan2
- RHD | c.662C>G p.P221R | Missense Mutation (SNP) | VAF 73/98 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59647186; called by muse, mutect2, varscan2
- RTN3 | c.2353T>A p.W785R (on ENST00000377819 / NM_001265589.2; = p.W766R on NM_201428.3) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.243); catalogued as COSV58032107; called by muse, mutect2, varscan2
- S1PR1 | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59514485; called by muse, mutect2, varscan2
- SEC14L2 | c.878A>G p.E293G | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as rs916030056, COSV57242596; called by muse, mutect2, varscan2
- SEC16A | c.6206A>G p.D2069G | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV51540134; called by muse, mutect2, varscan2
- SLC30A1 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV65361562; called by muse, mutect2, varscan2
- SNRK | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as rs889935483, COSV56066227; called by muse, mutect2, varscan2
- SPHK2 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs753977026, COSV55342037; called by muse, mutect2, varscan2
- TAS2R13 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs757671004, COSV66831889; called by muse, mutect2, varscan2
- TENM2 | c.6241G>A p.E2081K (on ENST00000518659 / NM_001122679.2; = p.E1842K on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1562332259, COSV69140611; called by muse, mutect2, varscan2
- TLR10 | c.829C>G p.R277G | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.049); catalogued as COSV100457401, COSV58302260; called by muse, mutect2, varscan2
- TMTC3 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV57126240; called by muse, mutect2, varscan2
- TSHZ3 | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs1429691355, COSV53681753, COSV53682036; called by muse, mutect2, varscan2
- VPS13C | c.1144C>A p.L382I (on ENST00000644861 / NM_020821.3; = p.L339I on NM_017684.5) | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs376883209; called by muse, mutect2, varscan2
- XRCC5 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV101079407, COSV101079809; called by muse, varscan2
- ZBTB17 | c.821C>G p.T274R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV65271815; called by muse, mutect2, varscan2
- ZBTB2 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs191541534, COSV57314011; called by muse, mutect2, varscan2
- ZDHHC15 | c.247C>G p.P83A | Missense Mutation (SNP) | VAF 51/62 reads (82%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.718); catalogued as COSV64903681; called by muse, mutect2, varscan2
- ZNF317 | c.1459_1462del p.L487Pfs*6 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs1242675964; called by mutect2, varscan2
- ZNF600 | c.851A>C p.N284T | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.138); catalogued as COSV57745041; called by muse, mutect2, varscan2
- ZNF644 | c.2258C>G p.S753* | Nonsense Mutation (SNP) | VAF 47/151 reads (31%) | catalogued as COSV100494653; called by muse, mutect2, varscan2
- AMER1 | c.331_332insCACA p.S111Tfs*3 | Frame Shift Ins (INS) | VAF 54/75 reads (72%) | called by mutect2, pindel, varscan2
- C12orf40 | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2
- CADM2 | c.1293dup p.E432Rfs*12 (on ENST00000407528 / NM_001167674.2; = p.E434Rfs*? on NM_153184.4) | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | called by mutect2, pindel
- CDK17 | c.1130_1135dup p.C377_I378dup | In Frame Ins (INS) | VAF 9/27 reads (33%) | called by mutect2, varscan2
- CUX2 | c.1962dup p.L655Sfs*49 | Frame Shift Ins (INS) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- DAPP1 | c.328_334delinsT p.A110_Q112delins* | Nonsense Mutation (DEL) | VAF 16/58 reads (28%) | called by pindel, varscan2*
- FBXO42 | c.799_803dup p.W268Cfs*26 | Frame Shift Ins (INS) | VAF 24/48 reads (50%) | called by mutect2, pindel, varscan2
- GOLM1 | c.590_591del p.R197Tfs*8 | Frame Shift Del (DEL) | VAF 55/225 reads (24%) | called by pindel, varscan2
- PCIF1 | c.1376_1377del p.S459Cfs*3 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by pindel, varscan2
- PLD5 | c.950_952delinsAA p.F317* (on ENST00000442594; = p.F255* on NM_001195811.1 and 1 other RefSeq transcript) | Nonsense Mutation (DEL) | VAF 25/58 reads (43%) | called by pindel, varscan2*
- USP12 | c.62_63insCC p.A22Rfs*3 | Frame Shift Ins (INS) | VAF 36/62 reads (58%) | called by pindel, varscan2
- AL592490.1 | c.2001C>T p.D667= | Silent (SNP) | VAF 79/100 reads (79%) | catalogued as rs535309463, COSV69427096; called by muse, mutect2, varscan2
- ARHGAP39 | c.2328C>T p.S776= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs138513361; called by muse, mutect2, varscan2
- ASB13 | c.279C>T p.C93= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs775589907, COSV100731403; called by muse, mutect2, varscan2
- CCT2 | c.1098C>T p.A366= | Silent (SNP) | VAF 83/233 reads (36%) | catalogued as rs772951985, COSV54741513; called by muse, mutect2, varscan2
- CHRNA9 | c.636G>A p.K212= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV59576145; called by muse, mutect2, varscan2
- CNTNAP4 | c.1737T>A p.G579= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV56699245; called by muse, mutect2, varscan2
- CSMD3 | c.8262C>T p.C2754= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as COSV99844236; called by muse, mutect2, varscan2
- CTSA | c.495G>A p.P165= | Silent (SNP) | VAF 42/72 reads (58%) | catalogued as rs1350708938, COSV51944819; called by muse, mutect2, varscan2
- DYRK3 | c.1608G>A p.V536= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs200820369, COSV65606706; called by muse, mutect2, varscan2
- FOXG1 | c.729G>A p.P243= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs774525510, COSV57395668; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR156 | c.1554C>T p.G518= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as rs755985390, COSV59939026; called by muse, mutect2, varscan2
- HTT | c.1432C>T p.L478= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV61868852; called by muse, mutect2, varscan2
- IGSF9B | c.3507G>A p.R1169= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs1484523251, COSV58072552; called by muse, mutect2, varscan2
- KLB | c.2448C>T p.G816= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as COSV99962418; called by muse, mutect2, varscan2
- KRT33B | c.909C>T p.S303= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs770330752, COSV52441438, COSV52442296; called by muse, mutect2, varscan2
- KRTAP13-3 | c.144G>T p.L48= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV61879419; called by muse, mutect2, varscan2
- LHX5 | c.798C>T p.D266= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs754316912, COSV55664122; called by muse, mutect2, varscan2
- NEK4 | c.1938A>G p.G646= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV51783215; called by muse, mutect2, varscan2
- NSMAF | c.1383G>A p.L461= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV50700251; called by muse, mutect2, varscan2
- PIKFYVE | c.5622T>C p.F1874= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV52248742; called by muse, mutect2, varscan2
- PRKAA2 | c.879G>T p.V293= | Silent (SNP) | VAF 56/100 reads (56%) | catalogued as COSV100983027; called by muse, mutect2, varscan2
- SLC4A5 | c.3219C>G p.L1073= | Silent (SNP) | VAF 83/188 reads (44%) | catalogued as COSV61032567; called by muse, mutect2, varscan2
- TMEM45A | c.513C>T p.F171= | Silent (SNP) | VAF 88/250 reads (35%) | catalogued as COSV60255818; called by muse, mutect2, varscan2
- TSHZ3 | c.2298G>A p.P766= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as rs368908849, COSV53672099; called by muse, mutect2, varscan2
- UTS2R | c.324G>A p.V108= | Silent (SNP) | VAF 46/69 reads (67%) | catalogued as COSV57453999; called by muse, mutect2, varscan2
- VNN1 | c.1134C>T p.Y378= | Silent (SNP) | VAF 71/116 reads (61%) | catalogued as rs370496023; called by muse, mutect2, varscan2
- RAB40AL | c.-2C>T | 5'UTR (SNP) | VAF 21/55 reads (38%) | catalogued as rs751487754, COSV99505238; called by muse, mutect2, varscan2
